Surgical pathology report (de-identified scan), TCGA case TCGA-94-8035, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Emory, specimen TCGA-94-8035-01A (Primary Tumor).

[page 1 of 5]
[REDACTED] Confidential Document [REDACTED]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of [REDACTED] regarding patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

Anat Path Reports

* Final Report *

Document Type: Anat Path Reports
Document Date: [REDACTED]
Document Status: Modified
Document Title: Histology
Encounter info: [REDACTED]

* Final Report *

APRPT (Verified)

Patient Name: [REDACTED]

MRN: [REDACTED]

Location: [REDACTED]

Client: [REDACTED]

Submitting

Phys: [REDACTED]

DOB: [REDACTED]

Gender: M

Acc #: [REDACTED]

Collected: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

Final Surgical Pathology Report

*** ADDENDUM PRESENT ***

Addendum Diagnosis

FINAL DIAGNOSIS REMAINS THE SAME.

Addendum Comment

AFB and GMS stains are negative on part A.

Final Pathologic Diagnosis

A. LYMPH NODE, LEVEL 6, EXCISION (AFS1,2):

- TWO LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/2).

Printed by: [REDACTED]

Printed on: [REDACTED]

[page 2 of 5]
Anat Path Reports

* Final Report *

- HYALINIZED GRANULOMAS.
- SEE COMMENT.

B. PLEURAL CLOT, LEFT, REMOVAL:

- REACTIVE MESOTHELIAL CELLS.
- NO CARCINOMA IDENTIFIED.

C. LYMPH NODE, LEFT LEVEL II, EXCISION:

- SIX LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/6).

D. LYMPH NODES, LEFT LEVEL 5, EXCISION:

- THREE LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/3).

E. LUNG, LEFT UPPER LOBE, EN BLOCK RESECTION WITH CHEST WALL:

- SQUAMOUS CELL CARCINOMA, POORLY DIFFERENTIATED (7CM).
- CARCINOMA INVADERS INTO ADJACENT RIBS AND INTERCOSTAL SOFT TISSUE.
- ALL SURGICAL MARGINS ARE NEGATIVE FOR CARCINOMA.
- PERINEURAL INVASION IS IDENTIFIED.
- TWO HILAR LYMPH NODES NEGATIVE FOR CARCINOMA (0/2).
- SEE SYNOPTIC REPORT.

F. LYMPH NODE, LEVEL 7, EXCISION:

- ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA (0/1).

Comment

ABF and GMS results will be reported in an addendum.

Electronically Signed by [REDACTED]

Assisted by: [REDACTED]

Addendum / Signed Out

Synoptic Worksheet

E. Left upper lobe en block chest wall resection of ribs 3,4,5; please freeze bronchial margin; short stitch-superior; long stitch-lateral:

Specimen:	Other: upper lobe and chest wall
Procedure:	Other: lobectomy and chest wall resection.
Specimen Integrity:	Intact
Specimen Laterality:	Left
Tumor Site:	Upper lobe

Printed by:
Printed on:

[page 3 of 5]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of [REDACTED] regarding patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

Anat Path Reports

* Final Report *

Tumor Focality:	Unifocal
Histologic Type:	Squamous cell carcinoma
Histologic Grade:	G3: Poorly differentiated
Tumor Size:	Greatest dimension: 7 cm
Visceral Pleura Invasion:	Present
Tumor Extension:	Parietal pleura
	Chest wall
Bronchial Margin:	Uninvolved by invasive carcinoma
	Involvement by squamous cell carcinoma in situ (CIS) not applicable
Vascular Margin:	Uninvolved by invasive carcinoma
Parenchymal Margin:	Uninvolved by invasive carcinoma
Parietal Pleural Margin:	Not applicable
Chest Wall Margin:	Uninvolved by invasive carcinoma
Other Attached Tissue Margin:	Tissue margin: rib margins
	Uninvolved by invasive carcinoma
All Margins Uninvolved By Invasive Carcinoma:	
	Distance of invasive carcinoma from closest margin: 4 mm
	Margin closest to invasive carcinoma:: chest wall soft tissue
Treatment Effect:	Not applicable
Lymph-Vascular Invasion:	Indeterminate
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT3: Tumor greater than 7 cm in greatest dimension; or Tumor of any size that directly invades any of the following: chest wall (including superior sulcus tumors), diaphragm, phrenic nerve, mediastinal pleura, parietal pericardium; or Tumor of any size in the main bronchus less than 2 cm distal to the carina but without involvement of the carina; or Tumor of any size associated with atelectasis or obstructive pneumonitis of the entire lung; or Tumors of any size with separate tumor nodule(s) in same lobe
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis
	Nodes examined: 14
	Nodes involved: 0
Distant Metastasis (pM):	Not applicable

Clinical History

Left thoracotomy. Left upper lobe cancer.

Specimen(s) Received

A: Level 6 lymph node
B: Left pleural clot
C: Left Level II lymph node
D: Left Level 5 lymph node

Printed by:
Printed on:

[page 4 of 5]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of [REDACTED] regarding patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

Anat Path Reports

* Final Report *

E: Left upper lobe en bloc chest wall resection of ribs 3,4,5; please freeze bronchial margin; short stitch-superior; long stitch-lateral
F: #7 Lymph node

Gross Description

Specimen A is received fresh for intraoperative consultation, labeled with the patient's name, medical record number as "level VI lymph node" and consists of two lymph nodes measuring 1.6 x 1.1 x 0.9 cm and 2.0 x 1.0 x 0.8 cm, respectively. Each lymph node is bisected and submitted for frozen section diagnosis. Dictated by [REDACTED]

Specimen B is received in formalin, labeled with the patient's name and medical record number submitted as "left pleural clot." The specimen consists of a fragment of soft tissue compatible with clotted blood measuring 5.0 x 2.0 x 0.5 cm. The specimen is grossly unremarkable. Representative sections are submitted in one cassette. [REDACTED]

Specimen C is received in formalin, labeled with the patient's name and medical record number submitted as "level 11 lymph node." The specimen consists of multiple fragments of lymph node tissue that measures 2.0 x 1.5 x 0.5 cm in aggregate. The specimen is submitted in its entirety in one cassette. [REDACTED]

Specimen D is received in formalin, labeled with the patient's name and medical record number submitted as "left level 5 lymph node." The specimen consists of fragments of lymphoid tissue that measures [REDACTED]

Specimen E is received fresh, labeled with the patient's name, medical record number submitted as "left upper lobe with en bloc chest wall resection of ribs." The specimen consists of a lobe of lung with adherent chest wall containing three ribs. The specimen is oriented per requisition with short stitch indicating superior aspect and the long stitch indicating the lateral aspect of the chest wall. The bronchial margin is identified. A shave section of the margin is taken for frozen section diagnosis. The remainder of the cryoblock is transferred to cassette "E1FS." The staple margin is inked black. The tumor mass does not appear to pucker the pleura and appears to be at the peripheral aspect of the lobe of the lung. Cross sectioning of the tumor mass reveals a 7.0 x 5.0 x 5.0 cm cystic necrotic mass. This mass measures 2.5 cm from the staple line margin and 3.5 cm from the bronchial margin. At the point where the tumor is adherent to the parietal chest wall it measures 2.5 cm to the superior aspect, 1.5 cm to the inferior aspect and 4.0 cm to the medial aspect and 2.5 cm to the lateral aspect. The outer chest wall (anterior to the tumor is inked black). Upon cross sectioning the ribs the middle two ribs appears grossly involved by the carcinoma. The most superior and most inferior ribs were grossly unaffected as well as the intercostal muscle between the inferior and middle inferior rib and superior and middle superior rib. The remainder of the lung is grossly unremarkable. The specimen will be submitted as follows. [REDACTED]

The specimen is received fresh with the patient's name [REDACTED] and medical record number and is designated as "#7 lymph node." The specimen consists of multiple dark grey-black soft tissue fragments measuring 2.0 x 1.5 x 0.8 cm in aggregate, entirely wrapped in a filter paper and submitted for permanent examination. Dictated by [REDACTED]

CASSETTE SUMMARY:

A1FS: Larger lymph node
A2FS: Smaller lymph node
E1FS: Remainder of the cryoblock
E2,3: Staple line margin, shave
E4: Perihilar lymph node, bisected
E5-8: Representative sections of tumor with respect to normal lung parenchyma

Printed by:
Printed on:

[page 5 of 5]
Anat Path Reports

* Final Report *

E9: Lateral rib margin (superior rib red, middle rib green, inferior rib blue)
E10: Medial rib margin, inked the same (superior red, middle green, inferior blue)
E11-18: Representative sections of tumor with respect to chest wall and middle rib
E19: Representative sections of peripheral upper lobe, uninvolved, submitted for decalcification
E20: Representative sections of central upper lobe, uninvolved

Intraoperative Consult Diagnosis

A1FS-A2FS: LEVEL VI LYMPH NODE (FROZEN SECTION): NEGATIVE FOR CARCINOMA.
Frozen section results were communicated to the surgical team and were repeated back by Lorraine on

12/15/11

E1FS: LUNG, LEFT UPPER LOBE, BRONCHIAL MARGIN (FROZEN SECTION): NEGATIVE FOR CARCINOMA.
Frozen section results were communicated to the surgical team and were repeated back by Oshiko on

12/15/11

at [REDACTED]

Pathologist: [REDACTED]

Microscopic Description

Microscopic examination performed.

Printed by:
Printed on:

Source: NCI Genomic Data Commons file c6e855c6-06d4-4782-828c-6a565621a8c0 (TCGA-94-8035.BA6DD2DF-43B6-414F-A5A7-160F31AF73FB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).